Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7QE, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7QE-01C (Primary Tumor).

[page 1 of 2]
Gender: Female	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology

Final Results

Surgical Pathology

CASE NUMBER:
DIAGNOSIS:

Final

1. Left renal mass margin #1, frozen section: Renal cortex, no tumor seen.
2. Left renal mass margin #2, frozen section: Renal medulla, no tumor seen.
3. Left renal mass, resection:
- Renal cell carcinoma, Chromophobe type.
- The tumor focally reached the renal capsule but does not infiltrate perinephric fat.
- Inked margins of resection are free of tumor.

*ICD-O-3
Carcinoma, renal cell
chromophobe type 8317/3
Site @ Kidney NOS 064.9
JW 9/24/13*

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History:
female with left renal mass Specimen Taken For Protocol:

PROCEDURE: Pre-Operative Diagnosis: left renal mass Post-Operative
Diagnosis:
left renal mass Operative Findings: left renal mass

SPECIMENS SUBMITTED: 1. ROUTINE + 3FR.SLIDES, Left renal mass margin #1 (1FS)
2. ROUTINE + 3FR.SLIDES, Left renal mass margin #2 (2FS)
3. KIDNEY, Left renal mass

INTRAOPERATIVE CONSULTATION:

1. "Left renal mass margin #1"
1FS diagnosis: Benign renal cortex, no tumor seen.
2. "Left renal mass margin #2"
2FS diagnosis: Benign renal medulla, no definite tumor seen.

This frozen section is performed by

GROSS DESCRIPTION:

[page 2 of 2]
Gender: Female		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology [OrderID: _____]	Final Results
-------------------------------------	---------------

1. "Left renal mass margin #1" is a red-tan soft tissue fragment measuring 0.3 x 0.3 x 0.2 cm, totally frozen as 1FS. In Surgical Pathology, the specimen is transferred to orange cassette FS for permanent processing.
2. "Left renal mass margin #2" is a red-tan soft tissue fragment measuring 0.2 x 0.2 x 0.2 cm, totally frozen as 2FS. In Surgical Pathology, the specimen is transferred to orange cassette FS for permanent processing.
3. "Left renal mass". It consists of a partial nephrectomy specimen (7.8 grams) measuring 2.5 x 3.7 x 2.3 cm, consists of portions of perirenal fat and portions of kidney. The overlying fat is inked in black and the surgical resection margin is inked in blue. The specimen is bivalved to reveal a 0.6-cm nodule with a gray-tan hemorrhagic smooth cut surface that lies within 0.1 cm from the overlying inked fat margin (black) and 1 cm from the renal surgical resection margin (blue). No procurement is performed. In Surgical Pathology, the specimen matches the above description. The specimen is serially sectioned and entirely submitted for permanent processing in white cassettes 3A-3G.

Gross description dictated by

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Criteria	9/13/13	Yes	No

Source: NCI Genomic Data Commons file febe3cf4-efd4-467b-af07-344e4351e329 (TCGA-KM-A7QE.8C1D7BB8-F0F2-4308-8413-9E5E14F80A26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).